Gene-level copy-number profile of tumor specimen REBC-AC93-TTP1-A from REBC case REBC-AC93, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC93-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ccf28f78-112b-461a-82ff-e9072809f31a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC93-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,249 have no estimate.
https://portal.gdc.cancer.gov/files/69e53664-b5d2-458a-82d5-a42a8ea046e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 427; copy number 2: 57,719; copy number 3: 219.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:126,860,665–126,885,878, 1 gene: ZBTB34.
- chr14:64,535,702–64,589,381, 3 genes (within-gene range 0–2): AL049869.3, HSPA2, PPP1R36.
- chr17:439,978–511,347, 2 genes (within-gene range 0–2): RFLNB, AC015853.2.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.
- chr21:8,701,461–8,761,335, 2 genes: CR381572.1, LINC01666.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 427. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
